Somatic mutation profile of tumor specimen 0DN51R from CCDI case PBCBAC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 13.4 years (4,898 days).
Specimen 0DN51R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e14d314f-af94-4b44-9968-919ebd3c7242.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN51H (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56775eed-8c5e-4b38-8674-54a5b5c5160a

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP42 | c.1605A>G p.I535M | Missense Mutation (SNP) | VAF 26/702 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs960835175; called by muse, mutect2
- DSPP | c.1253G>A p.G418E | Missense Mutation (SNP) | VAF 106/416 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.237); catalogued as COSV99217776; called by muse, mutect2, varscan2
- HAS2 | c.251C>G p.T84R | Missense Mutation (SNP) | VAF 131/597 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3C2B | c.2386A>G p.S796G | Missense Mutation (SNP) | VAF 27/573 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- TSPAN19 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 20/700 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- IGSF3 | c.489G>T p.L163= | Silent (SNP) | VAF 117/358 reads (33%) | called by muse, mutect2, varscan2
- TSPAN19 | c.366T>C p.I122= | Silent (SNP) | VAF 20/691 reads (3%) | catalogued as rs1267156464; called by muse, mutect2
- TTN | c.32876-50T>A | Intron (SNP) | VAF 8/187 reads (4%) | called by muse, mutect2
